Somatic mutation profile of tumor specimen TCGA-06-0190-02A (aliquot TCGA-06-0190-02A-01D-2280-08) from TCGA case TCGA-06-0190, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.5 years (22,835 days).
Specimen TCGA-06-0190-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f57c8030-3637-443a-9079-97b1758b28d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0190-10B (Blood Derived Normal), aliquot TCGA-06-0190-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5686190-7ff9-421e-abf6-e30c45d38535

The open-access MAF lists 105 somatic variants for this specimen: 83 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 21, Frame Shift Del 4, Splice Site 4, Splice Region 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP2 | c.2639+1G>A p.X880_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as rs746752313, COSV55557161; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2, varscan2
- PTEN | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779530981, CM033666, COSV64288954, COSV64292660; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2948C>T p.S983L (on ENST00000404938 / NM_001163941.2; = p.S538L on NM_178559.6) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.613); catalogued as COSV51706637; called by muse, mutect2, varscan2
- ABLIM3 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400412856; called by muse, mutect2
- ACTRT2 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201977075; called by muse, mutect2, varscan2
- ALDH3A1 | c.950-1G>T p.X317_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99855981; called by muse, mutect2
- ARHGEF5 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99282816; called by muse, mutect2, varscan2
- BBX | c.2203+1G>T p.X735_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57886093; called by muse, mutect2, varscan2
- CC2D1A | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs761771153, COSV58784031; called by muse, mutect2, varscan2
- CNTN6 | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63175010; called by muse, mutect2, varscan2
- CPNE3 | c.543G>A p.E181= | Splice Region (SNP) | VAF 6/112 reads (5%) | catalogued as rs1469285012; called by muse, mutect2
- CTSL | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV100446706; called by muse, mutect2
- CYP4F3 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as rs780899134, COSV55407196; called by muse, mutect2, varscan2
- DIPK1B | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100765481; called by muse, mutect2
- DNAAF1 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV57577571; called by muse, varscan2
- ENOSF1 | c.1243G>C p.E415Q (on ENST00000340116 / NM_001354066.2; = p.E381Q on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99201116; called by muse, mutect2
- EPPK1 | c.1136A>C p.Q379P | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1221407822; called by muse, mutect2, varscan2
- F5 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs770011773, HM971410, COSV63120371; called by muse, mutect2, varscan2
- FECH | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs954889536, COSV50490464; called by muse, mutect2, varscan2
- FLG | c.7640C>T p.S2547L | Missense Mutation (SNP) | VAF 103/406 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs369029216, COSV64242857; called by muse, mutect2, varscan2
- GH2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); catalogued as COSV100237049; called by muse, mutect2
- HPS3 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99937505; called by muse, mutect2
- IGHG3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs201961631; called by muse, mutect2, varscan2
- KCNG1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857083, COSV100857101; called by muse, mutect2, varscan2
- KCNV1 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV52086554; called by muse, mutect2, varscan2
- KIAA1217 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768275997, COSV56818364; called by muse, mutect2, varscan2
- KIFAP3 | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100847026; called by muse, mutect2, varscan2
- KMT2C | c.8140G>C p.D2714H | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51275994; called by muse, mutect2
- LAMA1 | c.3539G>A p.R1180H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs543432434, COSV67538610; called by muse, mutect2, varscan2
- MBD1 | c.225G>A p.K75= | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as COSV54002363; called by muse, mutect2, varscan2
- NIM1K | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV58142365; called by muse, mutect2, varscan2
- NLRP12 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs1346585060, COSV60748912; called by muse, mutect2, varscan2
- NTNG2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1181589867, COSV62367184; called by muse, mutect2, varscan2
- OR4Q3 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV59178913, COSV59180611; called by muse, mutect2, varscan2
- OR56B1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as COSV100402664; called by muse, mutect2
- PGGHG | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101164590; called by muse, mutect2, varscan2
- PIAS4 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53679471; called by muse, mutect2
- PIK3CG | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752602335, COSV63247110; called by muse, mutect2, varscan2
- POLD1 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV101486900; called by muse, mutect2
- RBM14 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100036860; called by muse, mutect2
- RELN | c.5282A>G p.N1761S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100634252; called by muse, mutect2
- SDK1 | c.3220T>C p.S1074P | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV101269609; called by muse, mutect2
- SERPING1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs139000758, CD087121; called by muse, mutect2, varscan2
- SLC12A7 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199620140; called by muse, mutect2, varscan2
- SPATA31D1 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV61194835, COSV61201105; called by muse, mutect2
- STAT1 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100738757, COSV63115890; called by muse, mutect2
- TDRD10 | c.1027A>C p.T343P | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99427556; called by muse, mutect2
- TIMD4 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs141557472, COSV50855913; called by muse, mutect2, varscan2
- TTLL12 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 117/370 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763918205, COSV53355575; called by muse, mutect2, varscan2
- TTN | c.32062C>T p.P10688S (on ENST00000591111; = p.P9761S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen benign (0.178); catalogued as rs758199108, COSV60068336; called by muse, mutect2, varscan2
- TXNRD1 | c.1258G>A p.V420I (on ENST00000525566 / NM_001093771.3; = p.V322I on NM_003330.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1264159001; called by muse, mutect2, varscan2
- USP49 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51897841; called by muse, mutect2, varscan2
- ZBTB21 | c.2245G>A p.V749I | Missense Mutation (SNP) | VAF 93/334 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs774567286, COSV60404382; called by muse, mutect2, varscan2
- ZCCHC4 | c.1346G>A p.G449D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57181529; called by muse, mutect2, varscan2
- ZNF335 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780577772, COSV59817450; called by muse, mutect2, varscan2
- ZNF688 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs201261814, COSV56301036; called by muse, mutect2, varscan2
- ZNF696 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs773246191; called by muse, mutect2, varscan2
- AHNAK2 | c.13676T>C p.V4559A | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ATP8B1 | c.1216G>T p.V406F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- B4GALT6 | c.253T>G p.S85A | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC18 | c.3405_3409del p.L1136Afs*32 (on ENST00000343253 / NM_001306076.1; = p.L1137Afs*32 on NM_206886.4) | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel
- CPNE5 | c.845A>C p.N282T | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2
- DGKQ | c.887-23_889del p.X296_splice | Splice Site (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- ENTHD1 | c.1596_1597dup p.Q533Lfs*21 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- H1-5 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAT1 | c.879_885del p.C294Ifs*10 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- KDM2B | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KNTC1 | c.3692T>C p.L1231S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMC1 | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- LUZP1 | c.2267T>C p.I756T | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGI1 | c.2482_2483del p.L828Gfs*4 (on ENST00000402939 / NM_001033057.2; = p.L856Gfs*4 on NM_004742.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- NARS1 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PIP4P1 | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIP4P1 | c.810C>A p.S270R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PPP2R5E | c.468A>T p.E156D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2
- RXFP1 | c.2078A>G p.H693R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A12 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- TAF5L | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by mutect2, varscan2
- TRIM42 | c.260del p.N87Tfs*45 | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | called by mutect2, pindel, varscan2
- TRIM42 | c.1145A>T p.K382M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CDK13 | c.3303T>G p.S1101= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV51701038; called by muse, varscan2
- COBL | c.1197G>A p.A399= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs770546382, COSV54348055; called by muse, mutect2, varscan2
- CRHR2 | c.939G>A p.L313= | Silent (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- CSF2RA | c.231C>T p.N77= | Silent (SNP) | VAF 99/493 reads (20%) | catalogued as rs767927197, COSV62623442; called by muse, mutect2, varscan2
- CYLD | c.867G>A p.A289= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs778051762, COSV61095059; called by muse, mutect2, varscan2
- DMAC2 | c.549T>C p.G183= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs1367619346, COSV55728034; called by muse, mutect2
- FCRL2 | c.981T>A p.S327= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as COSV100829959; called by muse, mutect2
- GABRA4 | c.1227T>C p.H409= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV51929287; called by muse, mutect2, varscan2
- KIAA1210 | c.339T>C p.D113= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- KPNA1 | c.1260A>G p.V420= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1253182779; called by muse, mutect2, varscan2
- LRRC34 | c.1293T>C p.N431= (on ENST00000446859 / NM_001172779.2; = p.N399= on NM_153353.5) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1198086566; called by muse, mutect2, varscan2
- MYBPC1 | c.2760G>A p.E920= (on ENST00000550270 / NM_206820.2; = p.E927= on NM_002465.4) | Silent (SNP) | VAF 52/253 reads (21%) | called by muse, mutect2, varscan2
- PRSS35 | c.240T>C p.D80= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV100864119; called by muse, mutect2
- RPL7L1 | c.352A>C p.R118= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV100491755; called by muse, mutect2
- SIGLEC11 | c.1266G>A p.E422= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV70222025, COSV70222129; called by muse, mutect2
- SLC46A3 | c.864A>T p.S288= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- SNX1 | c.489A>G p.V163= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV56038588; called by muse, mutect2, varscan2
- SPIC | c.528C>T p.Y176= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs759289491, COSV54690341; called by muse, mutect2, varscan2
- WDR26 | c.1203A>G p.L401= (on ENST00000414423 / NM_001379403.1; = p.L301= on NM_025160.7) | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- ZNF709 | c.1926A>G p.*642= | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as COSV101172240; called by muse, mutect2
- ZSCAN22 | c.1251C>T p.F417= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- DCHS2 | n.602C>T | RNA (SNP) | VAF 27/101 reads (27%) | catalogued as COSV59728638; called by muse, mutect2, varscan2
